Somatic mutation profile of tumor specimen TCGA-D3-A8GP-06A (aliquot TCGA-D3-A8GP-06A-11D-A372-08) from TCGA case TCGA-D3-A8GP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-D3-A8GP-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95400afd-5ce6-4464-857c-2d5ca181988d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GP-10A (Blood Derived Normal), aliquot TCGA-D3-A8GP-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb4a0ff4-e72c-4f3f-bfb8-bd064dce47a2

The open-access MAF lists 691 somatic variants for this specimen: 482 protein-altering or splice-affecting, 194 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 423, Silent 194, Nonsense Mutation 34, Splice Region 8, Splice Site 8, Intron 6, Frame Shift Del 6, RNA 5, 5'UTR 2, 5'Flank 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMD4B | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV68328045; called by muse, mutect2, varscan2
- MAP2K1 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 76/128 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs1057519729, COSV61068787; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAMP | c.274+1G>A p.X92_splice | Splice Site (SNP) | VAF 82/126 reads (65%) | catalogued as COSV99297851; called by muse, mutect2, varscan2
- ABCA12 | c.6869G>A p.G2290E (on ENST00000272895 / NM_173076.3; = p.G1972E on NM_015657.3) | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789030; called by muse, mutect2, varscan2
- ABCA12 | c.6868G>A p.G2290R (on ENST00000272895 / NM_173076.3; = p.G1972R on NM_015657.3) | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789034; called by muse, mutect2, varscan2
- ABCB5 | c.2197G>A p.E733K (on ENST00000404938 / NM_001163941.2; = p.E288K on NM_178559.6) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.287); catalogued as rs779350155, COSV99327801; called by muse, mutect2, varscan2
- ABCD2 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340465804, COSV58049889; called by muse, mutect2, varscan2
- ABI3BP | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs373865185; called by muse, mutect2, varscan2
- ABLIM3 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100448166; called by muse, mutect2, varscan2
- ACAD10 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253538718, COSV100563948; called by muse, mutect2, varscan2
- ACIN1 | c.2143G>T p.A715S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs372380278; called by muse, mutect2, varscan2
- ACSF2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.574); catalogued as COSV99366105; called by muse, mutect2, varscan2
- ADAD1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs78087673, COSV99635305; called by muse, mutect2, varscan2
- ADAM18 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 41/88 reads (47%) | catalogued as COSV99695165; called by muse, mutect2, varscan2
- ADAM2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV99696992; called by muse, mutect2, varscan2
- ADGRL3 | c.1719A>T p.E573D (on ENST00000506720 / NM_001322402.2; = p.E505D on NM_015236.6) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101546931; called by muse, mutect2, varscan2
- ADGRL4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs771201747, COSV66061203; called by muse, mutect2, varscan2
- ADGRV1 | c.11064A>G p.I3688M | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV101315644; called by muse, mutect2, varscan2
- ADGRV1 | c.11581G>A p.D3861N | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1311978141, COSV101315645, COSV101316332; called by muse, mutect2, varscan2
- ADH1C | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as COSV101565167; called by muse, mutect2, varscan2
- AGTPBP1 | c.3641T>A p.V1214E (on ENST00000357081 / NM_001330701.2; = p.V1174E on NM_015239.2) | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV100429458; called by muse, mutect2, varscan2
- AIRE | c.882G>A p.K294= | Splice Region (SNP) | VAF 34/59 reads (58%) | catalogued as COSV99381024; called by muse, mutect2, varscan2
- AKR1B15 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs866009184, COSV71152976; called by muse, mutect2, varscan2
- ALB | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs749776790, COSV99891030; called by muse, mutect2, varscan2
- ALPK1 | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as COSV99453446; called by muse, mutect2, varscan2
- ALX3 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100873872; called by muse, mutect2, varscan2
- AMIGO2 | c.454C>G p.H152D | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99873506; called by muse, mutect2, varscan2
- AMY1A | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs1356493608, COSV100915778; called by mutect2, varscan2
- ANK2 | c.4307C>T p.S1436F | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100000463; called by muse, mutect2, varscan2
- ANKRD11 | c.5681C>T p.P1894L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as rs760261187, COSV99968691; called by muse, mutect2, varscan2
- APCS | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866542574, COSV54818126; called by muse, mutect2, varscan2
- ARHGAP33 | c.1233G>A p.E411= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs772233109, COSV99137748; called by muse, varscan2
- ARHGAP39 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99430570; called by muse, mutect2, varscan2
- ARMC4 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 40/41 reads (98%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV100536504; called by muse, mutect2, varscan2
- ASH1L | c.4745G>A p.S1582N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100853231; called by muse, mutect2, varscan2
- ASTN1 | c.1610C>T p.T537I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs1225191590, COSV99920884; called by muse, mutect2, varscan2
- ATP13A3 | c.2644G>T p.G882C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757227841, COSV99756556; called by muse, mutect2, varscan2
- ATP8A1 | c.2639A>G p.N880S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as rs1279809748, COSV100045435; called by muse, mutect2, varscan2
- ATP8B1 | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs144656719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B1 | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV99377023; called by muse, mutect2, varscan2
- ATXN3L | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 48/50 reads (96%) | catalogued as rs1252801787, COSV101019398, COSV66075342; called by muse, mutect2, varscan2
- B3GALT1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV59908505; called by muse, mutect2, varscan2
- B4GALT4 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as rs750912103, COSV100785775; called by muse, mutect2, varscan2
- B4GALT4 | c.767G>A p.W256* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as rs1346943151, COSV100785776; called by muse, mutect2, varscan2
- BAG4 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV99781764; called by muse, mutect2, varscan2
- BBS9 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99625972, COSV99626905; called by muse, mutect2, varscan2
- BFAR | c.1176G>T p.R392S | Missense Mutation (SNP) | VAF 111/156 reads (71%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV99902095; called by muse, mutect2, varscan2
- BMP2 | c.289C>G p.H97D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV101122064; called by muse, mutect2, varscan2
- BMP5 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100895831; called by muse, mutect2, varscan2
- BMPER | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779219; called by muse, mutect2, varscan2
- BRWD1 | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); catalogued as rs1291551417, COSV100313063; called by muse, mutect2, varscan2
- BTNL3 | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100732189, COSV61564829; called by muse, mutect2, varscan2
- C16orf90 | c.551G>A p.R184H (on ENST00000399645 / NM_001353385.2; = p.R175H on NM_001080524.2) | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs371199813; called by muse, varscan2
- C19orf57 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV100694654; called by muse, mutect2, varscan2
- C8orf34 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV61374150; called by muse, mutect2, varscan2
- CACNA1E | c.4671T>G p.I1557M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100701554; called by muse, mutect2, varscan2
- CACNA1E | c.5516C>T p.T1839I | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100701556; called by muse, mutect2
- CACNA1I | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.24); catalogued as COSV60800827; called by muse, mutect2, varscan2
- CACNA2D4 | c.2208G>A p.M736I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1309685986, COSV99765292; called by muse, mutect2, varscan2
- CACNB2 | c.134G>A p.G45E (on ENST00000324631 / NM_201596.3; = p.G17E on NM_201571.4) | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as COSV99993585; called by muse, mutect2, varscan2
- CACNG8 | c.366C>T p.L122= | Splice Region (SNP) | VAF 22/30 reads (73%) | catalogued as rs755790899, COSV99554905; called by muse, mutect2, varscan2
- CADM3 | c.611G>A p.G204E (on ENST00000368125 / NM_001127173.3; = p.G238E on NM_021189.5) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as COSV63685114; called by muse, mutect2, varscan2
- CALCRL | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV66474332; called by muse, mutect2, varscan2
- CAMTA1 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 24/35 reads (69%) | catalogued as COSV100347488; called by muse, mutect2, varscan2
- CARD11 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV67798697; called by muse, mutect2, varscan2
- CCBE1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1216440169, COSV101232798, COSV67949532; called by muse, mutect2, varscan2
- CCBE1 | c.213G>A p.R71= | Splice Region (SNP) | VAF 39/89 reads (44%) | catalogued as COSV101232766; called by muse, mutect2, varscan2
- CCDC102B | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.245); catalogued as COSV60147631; called by muse, mutect2, varscan2
- CCDC17 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100601694; called by muse, mutect2
- CCDC73 | c.2677A>G p.K893E | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV100066828, COSV58795953; called by muse, mutect2, varscan2
- CCDC8 | c.842A>T p.Q281L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100281947; called by muse, mutect2, varscan2
- CCDC85A | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs764849312, COSV68154259; called by muse, mutect2, varscan2
- CCDC85A | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated, low confidence (0.58); PolyPhen possibly damaging (0.787); catalogued as COSV101339420; called by muse, mutect2, varscan2
- CD163 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 50/71 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754173408, COSV100775744; called by muse, mutect2, varscan2
- CD163L1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100549836; called by muse, mutect2, varscan2
- CD244 | c.622G>A p.E208K (on ENST00000368033 / NM_001166663.2; = p.E203K on NM_016382.4) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.314); catalogued as rs773780845, COSV59238932; called by muse, mutect2, varscan2
- CD46 | c.188A>G p.K63R | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.373); catalogued as COSV100522817; called by muse, mutect2, varscan2
- CDADC1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV99212525; called by muse, mutect2, varscan2
- CDC73 | c.127T>A p.W43R | Missense Mutation (SNP) | VAF 107/209 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100813751; called by muse, mutect2, varscan2
- CDH4 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 86/110 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848558; called by muse, mutect2, varscan2
- CDH7 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as rs774959226, COSV100541758; called by muse, mutect2, varscan2
- CDH8 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.148); catalogued as rs1567404075, COSV100180310; called by muse, mutect2, varscan2
- CDHR3 | c.2147T>A p.I716N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100488116; called by muse, mutect2, varscan2
- CEACAM18 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV67284416; called by muse, mutect2, varscan2
- CENPF | c.6364G>A p.E2122K | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004159556, COSV65274741; called by muse, mutect2, varscan2
- CEP192 | c.5798C>T p.S1933F | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.73); PolyPhen benign (0.084); catalogued as COSV58060830, COSV58070230; called by muse, mutect2, varscan2
- CEP250 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100698820; called by muse, mutect2, varscan2
- CFAP54 | c.7327C>T p.L2443F | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.725); catalogued as COSV100733035, COSV61570911; called by muse, mutect2, varscan2
- CHAF1A | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.879); catalogued as rs1234498774, COSV100010975; called by muse, mutect2
- CILP2 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs759870551, COSV99364458; called by muse, mutect2, varscan2
- CLN3 | c.728C>T p.S243F (on ENST00000360019 / NM_001286104.2; = p.S267F on NM_000086.2) | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100343160; called by muse, mutect2, varscan2
- CLVS1 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.701); catalogued as rs768010044, COSV99073591; called by muse, mutect2, varscan2
- CNTN5 | c.2239C>T p.R747* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as rs780931539, COSV54291267; called by muse, mutect2, varscan2
- CNTNAP3 | c.3392C>T p.S1131L | Missense Mutation (SNP) | VAF 81/90 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV99904407; called by muse, mutect2, varscan2
- COG6 | c.1246A>G p.N416D | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs750661302, COSV100742663; called by muse, mutect2, varscan2
- COL4A3 | c.2143G>A p.G715S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196105825, COSV67417865; called by muse, mutect2, varscan2
- COL4A6 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 133/137 reads (97%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.869); catalogued as COSV57860701; called by muse, mutect2, varscan2
- COL5A1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 94/100 reads (94%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.935); catalogued as rs776904091, COSV65665757; called by muse, mutect2, varscan2
- COL6A6 | c.4427G>A p.G1476D | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs995786769, COSV100650025; called by muse, mutect2, varscan2
- CR1L | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 79/199 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs192078528; called by muse, mutect2, varscan2
- CRAT | c.517T>A p.Y173N | Missense Mutation (SNP) | VAF 167/172 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100539885; called by muse, mutect2, varscan2
- CSMD1 | c.9754G>A p.G3252S (on ENST00000520002; = p.G3251S on NM_033225.6) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100145458; called by muse, mutect2, varscan2
- CSMD1 | c.3670C>T p.P1224S (on ENST00000520002; = p.P1223S on NM_033225.6) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1243577739, COSV59343318; called by muse, mutect2, varscan2
- CYP4B1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs745623064, COSV54724715; called by muse, mutect2, varscan2
- CYP4F11 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV99930714; called by muse, mutect2, varscan2
- DCAF4L2 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.101); catalogued as rs749382024, COSV60478718; called by muse, mutect2, varscan2
- DDR2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 53/141 reads (38%) | catalogued as COSV100906302; called by muse, mutect2, varscan2
- DDX3Y | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV100267490; called by muse, mutect2, varscan2
- DENND2B | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs1245361475, COSV100567293; called by muse, mutect2, varscan2
- DHX16 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs773652903, COSV100905154; called by muse, mutect2, varscan2
- DIO3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as COSV100832173, COSV63773017; called by muse, mutect2, varscan2
- DLG1 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1178053626, COSV100014913; called by muse, mutect2, varscan2
- DNAH10 | c.7774G>A p.E2592K (on ENST00000409039; = p.E2531K on NM_207437.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1267563266, COSV68990021; called by muse, mutect2
- DNAH2 | c.5749G>A p.E1917K | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs771959734, COSV101209101; called by muse, mutect2, varscan2
- DNAH5 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs1198674256, COSV54225467; called by muse, mutect2, varscan2
- DNAH5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV54239692; called by muse, mutect2, varscan2
- DNAJC10 | c.524T>A p.V175E | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99899009; called by muse, mutect2, varscan2
- DNM3 | c.1662A>T p.E554D (on ENST00000355305 / NM_001350206.2; = p.E544D on NM_015569.5) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as COSV100797898; called by muse, mutect2, varscan2
- DOCK4 | c.3968G>A p.G1323E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261350295, COSV69855143; called by muse, varscan2
- DOHH | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs758770567, COSV99170991; called by muse, mutect2, varscan2
- DOHH | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99170993; called by muse, mutect2, varscan2
- DPYD | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100928862; called by muse, mutect2, varscan2
- DQX1 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771135773, COSV66353633; called by muse, mutect2, varscan2
- EBI3 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696031; called by muse, mutect2, varscan2
- ECHDC1 | c.899C>T p.A300V (on ENST00000531967 / NM_001139510.1; = p.A294V on NM_001002030.2) | Missense Mutation (SNP) | VAF 97/104 reads (93%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as COSV100541620; called by muse, mutect2, varscan2
- EFS | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV99391439; called by muse, mutect2, varscan2
- EIF4G3 | c.4574C>T p.A1525V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99943711; called by muse, mutect2, varscan2
- EMILIN2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as rs147386217, COSV54421566; called by muse, mutect2
- EML3 | c.1958T>A p.V653E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV99604121; called by muse, mutect2, varscan2
- EML4 | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs962247670, COSV100580756, COSV59295784; called by muse, mutect2, varscan2
- EMP3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as rs748467464, COSV99507037; called by muse, varscan2
- ENAM | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 138/291 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV101252980; called by muse, mutect2, varscan2
- EPHA3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866821420, COSV60695193, COSV60706143; called by muse, mutect2, varscan2
- EPHA5 | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99897376; called by muse, mutect2, varscan2
- ERBB4 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53536354; called by muse, mutect2, varscan2
- ERC2 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV55658796; called by muse, mutect2, varscan2
- EYA4 | c.1449G>A p.W483* (on ENST00000531901 / NM_001301013.1; = p.W477* on NM_004100.5) | Nonsense Mutation (SNP) | VAF 32/36 reads (89%) | catalogued as rs866613309, COSV100765451; called by muse, mutect2, varscan2
- F10 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV100979166; called by muse, mutect2, varscan2
- F12 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs376689925, COSV53691282; called by muse, mutect2, varscan2
- FASN | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs747672060, COSV100147514; called by muse, varscan2
- FAT1 | c.7429C>T p.Q2477* | Nonsense Mutation (SNP) | VAF 139/286 reads (49%) | catalogued as COSV101499166, COSV101499694; called by muse, mutect2, varscan2
- FAT4 | c.13306C>T p.P4436S | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100627761; called by muse, mutect2, varscan2
- FCGR2C | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100912594; called by muse, mutect2, varscan2
- FCRLA | c.937C>T p.P313S (on ENST00000367959; = p.P290S on NM_032738.4) | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs764922944, COSV52684992; called by muse, mutect2, varscan2
- FERMT1 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV99451299; called by muse, mutect2, varscan2
- FGF10 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866583243, COSV99240295; called by muse, mutect2, varscan2
- FLG | c.8939C>T p.S2980F | Missense Mutation (SNP) | VAF 163/778 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs569026847; called by muse, mutect2
- FLNC | c.4970G>A p.R1657Q | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs374294752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs199942873, COSV56123360; called by muse, mutect2, varscan2
- FOXD4L5 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1300781397, COSV101073073; called by muse, mutect2, varscan2
- FRA10AC1 | c.906-1G>T p.X302_splice | Splice Site (SNP) | VAF 21/24 reads (88%) | catalogued as rs1278968336, COSV100784675; called by muse, mutect2, varscan2
- FRMD6 | c.1859T>G p.F620C (on ENST00000344768 / NM_001267046.2; = p.F612C on NM_152330.4) | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100655616; called by muse, mutect2, varscan2
- FRY | c.1793G>A p.R598K | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV66571431; called by muse, mutect2, varscan2
- GAK | c.3452C>T p.S1151L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs771564068, COSV100033322; called by muse, mutect2, varscan2
- GALNT11 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs570188437, COSV57425451; called by muse, mutect2, varscan2
- GALNT2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV100795562; called by muse, mutect2, varscan2
- GBA | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100516269; called by muse, mutect2, varscan2
- GCN1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0.108); catalogued as rs774620630, COSV100324835; called by muse, mutect2, varscan2
- GIMAP4 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55431866; called by muse, mutect2, varscan2
- GLB1L3 | c.1879C>T p.H627Y | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1205796889, COSV101345128; called by muse, mutect2, varscan2
- GPR153 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1265024069, COSV100928483; called by muse, mutect2, varscan2
- GRB10 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100239980; called by muse, mutect2, varscan2
- GRIK4 | c.2265C>G p.V755= | Splice Region (SNP) | VAF 21/43 reads (49%) | catalogued as COSV101483534; called by muse, mutect2, varscan2
- GRIN2A | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 79/117 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749732928, COSV100408938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIP1 | c.838A>T p.I280L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99668588; called by muse, mutect2, varscan2
- GRM4 | c.1931T>G p.I644S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100945963; called by muse, mutect2, varscan2
- GTSF1L | c.311G>A p.W104* | Nonsense Mutation (SNP) | VAF 50/75 reads (67%) | catalogued as COSV100883907; called by muse, mutect2, varscan2
- H2AC1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs371440858; called by muse, mutect2, varscan2
- HACD3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as rs570046325, COSV99970955; called by muse, mutect2, varscan2
- HCAR2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.115); catalogued as COSV100186448; called by mutect2, varscan2
- HCN4 | c.2321G>A p.W774* | Nonsense Mutation (SNP) | VAF 21/33 reads (64%) | catalogued as rs1385607480, COSV99983453; called by muse, mutect2, varscan2
- HMCN1 | c.13678C>T p.L4560F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54939071; called by muse, mutect2, varscan2
- HMCN1 | c.13679T>A p.L4560H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.526); catalogued as COSV99626051; called by muse, mutect2, varscan2
- HPRT1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 127/128 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV53777620; called by muse, mutect2, varscan2
- HRNR | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 126/249 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV64257805; called by muse, mutect2, varscan2
- HSPA13 | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.357); catalogued as COSV99579957; called by muse, mutect2, varscan2
- HTR3A | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV100248334; called by muse, mutect2, varscan2
- HTR3A | c.1139-2A>T p.X380_splice | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100248335; called by muse, mutect2, varscan2
- IFNL1 | c.250-1G>A p.X84_splice | Splice Site (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100373625; called by muse, mutect2, varscan2
- IGHG2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs766686642; called by muse, mutect2, varscan2
- IGKV2-28 | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1229890796; called by mutect2, varscan2
- IGKV5-2 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764028680; called by muse, mutect2, varscan2
- IGSF1 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 50/54 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV100811959; called by muse, mutect2, varscan2
- IGSF22 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as rs749940366, COSV100079359; called by muse, mutect2, varscan2
- IGSF9 | c.1508T>G p.V503G (on ENST00000368094 / NM_001135050.2; = p.V487G on NM_020789.4) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV100829604; called by muse, mutect2, varscan2
- IL12RB2 | c.140T>A p.V47D | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99254843; called by muse, mutect2, varscan2
- INSRR | c.2851A>G p.T951A | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.297); catalogued as COSV100947284; called by muse, mutect2, varscan2
- KANK4 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV100587200, COSV62988564; called by muse, mutect2, varscan2
- KCNN1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV99715727, COSV99716384; called by muse, mutect2, varscan2
- KCTD19 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 94/199 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs769658974, COSV58570966; called by muse, mutect2, varscan2
- KIAA0100 | c.6140C>T p.S2047F | Missense Mutation (SNP) | VAF 82/139 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV56381543; called by muse, mutect2, varscan2
- KIF1C | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs139942468; called by muse, mutect2, varscan2
- KIF20B | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 45/46 reads (98%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780902590, COSV99589679; called by muse, mutect2, varscan2
- KIF26A | c.1666C>G p.P556A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100180948, COSV59471123; called by muse, mutect2, varscan2
- KIF4B | c.3656A>G p.N1219S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.164); catalogued as COSV101469218; called by muse, mutect2, varscan2
- KLF6 | c.677-2A>G p.X226_splice | Splice Site (SNP) | VAF 26/27 reads (96%) | catalogued as COSV99434953; called by muse, mutect2, varscan2
- KLHL26 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1345056593, COSV99963061; called by muse, mutect2, varscan2
- KLK13 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV50066982; called by muse, mutect2, varscan2
- KPTN | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs748568252, COSV57644334; called by muse, mutect2, varscan2
- KRTAP5-2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | PolyPhen benign (0.211); catalogued as COSV101295070; called by muse, mutect2, varscan2
- LAMA2 | c.4037G>A p.G1346E | Missense Mutation (SNP) | VAF 37/39 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70338493; called by muse, mutect2, varscan2
- LAMA5 | c.690C>T p.I230= | Splice Region (SNP) | VAF 5/22 reads (23%) | catalogued as rs371953116; called by muse, mutect2, varscan2
- LCE3B | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100167505; called by muse, mutect2, varscan2
- LCN9 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99479516, COSV99479701; called by muse, mutect2, varscan2
- LPIN1 | c.533A>T p.D178V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs769176403, COSV99877259; called by muse, varscan2
- LRIT1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1245352599, COSV100928044, COSV64512410; called by muse, mutect2, varscan2
- LRP2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs747942310, COSV55539979; called by muse, mutect2, varscan2
- LRRC34 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.307); catalogued as COSV100336223; called by muse, mutect2, varscan2
- LRRC66 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100602882; called by muse, mutect2, varscan2
- LRRIQ3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs765391855, COSV63041539; called by muse, mutect2, varscan2
- LRTM2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.378); catalogued as COSV99765291, COSV99766766; called by muse, mutect2, varscan2
- LY6G5B | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101020811; called by muse, mutect2, varscan2
- MACIR | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.47); catalogued as rs781884566, COSV60634695; called by muse, mutect2, varscan2
- MAGEB4 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as COSV100974898; called by muse, mutect2, varscan2
- MAN2A2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs753230592, COSV64638746; called by muse, mutect2, varscan2
- MAP2K5 | c.215T>A p.V72E | Missense Mutation (SNP) | VAF 112/191 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99459903; called by muse, mutect2, varscan2
- MAPK13 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV99274979; called by muse, mutect2, varscan2
- MCTP1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV56534695; called by muse, mutect2, varscan2
- MECOM | c.2995C>T p.P999S (on ENST00000468789 / NM_001105078.4; = p.P1187S on NM_004991.4) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.251); catalogued as rs1157315856, COSV99244342; called by muse, mutect2, varscan2
- MEOX2 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs766320553, COSV100012023; called by muse, mutect2, varscan2
- MKRN3 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV58810060, COSV58811499; called by muse, mutect2, varscan2
- MMP27 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV52780429; called by muse, mutect2, varscan2
- MROH2B | c.1709G>A p.W570* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV101270593; called by muse, mutect2
- MRPL17 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs140275479, COSV99996813; called by muse, mutect2, varscan2
- MUC16 | c.17840C>T p.S5947L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.065); catalogued as rs1295699351, COSV101198872; called by muse, mutect2, varscan2
- MUC16 | c.8900C>G p.S2967C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV101198874; called by muse, mutect2, varscan2
- MUC16 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as rs758480970, COSV67482830; called by muse, mutect2, varscan2
- MUC7 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.03); catalogued as COSV59217349; called by muse, mutect2, varscan2
- MYH14 | c.4972G>A p.E1658K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs774603941, COSV51835645; called by muse, mutect2, varscan2
- MYO16 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99193710; called by muse, mutect2, varscan2
- MYO1H | c.570G>A p.Q190= | Splice Region (SNP) | VAF 16/22 reads (73%) | catalogued as rs1433113438, COSV100183271; called by muse, mutect2, varscan2
- MYOCD | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs767925734, COSV58498174, COSV58501218; called by muse, mutect2, varscan2
- N4BP2 | c.4902G>A p.M1634I | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs754246441, COSV99788352; called by muse, mutect2, varscan2
- NAV1 | c.3057G>C p.E1019D | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99818484; called by muse, mutect2, varscan2
- NBEA | c.6189T>A p.H2063Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.191); catalogued as rs1260708842, COSV100078030; called by muse, mutect2, varscan2
- NBEAL1 | c.4887G>C p.Q1629H | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs750972653, COSV101495624; called by muse, mutect2, varscan2
- NCOR1 | c.6761T>C p.F2254S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs768282882, COSV99248467; called by muse, mutect2, varscan2
- NDST4 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV99995078, COSV99995887; called by muse, mutect2, varscan2
- NEB | c.14614G>A p.D4872N | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV51459441; called by muse, mutect2, varscan2
- NEB | c.4366G>T p.E1456* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as COSV99417635; called by muse, mutect2, varscan2
- NEDD1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57143189, COSV99900820; called by muse, mutect2, varscan2
- NEU4 | c.856C>T p.P286S (on ENST00000391969 / NM_001167602.3; = p.P298S on NM_080741.4) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100371896; called by muse, mutect2, varscan2
- NFKB1 | c.2020G>A p.G674R (on ENST00000394820 / NM_001382627.1; = p.G675R on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV56955148, COSV99896818; called by muse, mutect2, varscan2
- NIPSNAP3B | c.230T>G p.F77C | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101044438; called by muse, mutect2, varscan2
- NKAIN3 | c.203G>A p.W68* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as rs1252504509, COSV60655331; called by muse, mutect2, varscan2
- NLRP10 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV60781120; called by muse, mutect2, varscan2
- NLRP12 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1324521711, COSV60757704; called by muse, mutect2, varscan2
- NLRP13 | c.2564T>C p.I855T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1313939749, COSV100738097; called by muse, mutect2, varscan2
- NLRP5 | c.3051G>A p.M1017I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV66765557; called by muse, mutect2, varscan2
- NLRP8 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV99404927; called by muse, mutect2, varscan2
- NLRP9 | c.1100T>C p.L367S | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV60469228; called by muse, mutect2, varscan2
- NMUR2 | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54918431, COSV54919759; called by muse, mutect2, varscan2
- NOC3L | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 80/86 reads (93%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); catalogued as COSV100993283; called by muse, mutect2, varscan2
- NOS3 | c.1181G>A p.W394* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99871356; called by muse, mutect2, varscan2
- NOX4 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV99629993; called by muse, mutect2, varscan2
- NPHP3 | c.2471T>A p.L824Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.543); catalogued as rs1211967673, COSV100446691; called by muse, mutect2, varscan2
- NPHS1 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as rs760440966, COSV62286459; called by muse, mutect2
- NPTX2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs565519639, COSV55716887; called by muse, mutect2, varscan2
- NTN5 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs576000113, COSV99539312; called by muse, mutect2, varscan2
- NXPE3 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs773405177, COSV99839839; called by muse, mutect2, varscan2
- OBSCN | c.21028A>G p.T7010A | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1373705873, COSV100802471; called by muse, mutect2, varscan2
- OPLAH | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs1288181246, COSV101470742; called by muse, mutect2, varscan2
- OPRK1 | c.493A>T p.K165* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV99653834; called by muse, mutect2, varscan2
- OR11G2 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1003985065, COSV100640079, COSV62133089; called by muse, mutect2, varscan2
- OR1L6 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 59/62 reads (95%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV100490847; called by muse, mutect2, varscan2
- OR2A7 | c.500T>A p.F167Y | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV101512199; called by muse, mutect2, varscan2
- OR2A7 | c.499T>A p.F167I | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV101512200; called by muse, varscan2
- OR2C1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV59240770; called by muse, mutect2, varscan2
- OR2L3 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 130/356 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100741939; called by muse, mutect2, varscan2
- OR2T11 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100424724, COSV100425015, COSV58185468; called by muse, mutect2, varscan2
- OR2T34 | c.531G>C p.R177S | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100170301, COSV60899697; called by muse, mutect2, varscan2
- OR51B6 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100970910; called by muse, mutect2
- OR51F2 | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs1331501125, COSV100437953; called by muse, mutect2, varscan2
- OR51I2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100413399, COSV58297792; called by muse, mutect2, varscan2
- OR51M1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1010504878, COSV60783841; called by muse, mutect2, varscan2
- OR52A1 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100200444; called by muse, mutect2, varscan2
- OR52B4 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68769482; called by muse, mutect2, varscan2
- OR52K1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56904585; called by muse, mutect2, varscan2
- OR52M1 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs765807772, COSV64172610; called by muse, mutect2
- OR5F1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.182); catalogued as COSV53548788; called by muse, mutect2, varscan2
- OR6K6 | c.496C>T p.P166S (on ENST00000368144; = p.P142S on NM_001005184.1) | Missense Mutation (SNP) | VAF 82/132 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs753675767, COSV63744918, COSV63744995; called by muse, mutect2, varscan2
- OR8D1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1254736351, COSV63442643; called by muse, mutect2, varscan2
- OR8H2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 132/319 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868862487, COSV57943241; called by muse, mutect2, varscan2
- OTOP1 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99587464, COSV99587502; called by muse, mutect2
- PAPPA | c.3382C>T p.Q1128* | Nonsense Mutation (SNP) | VAF 41/44 reads (93%) | catalogued as rs1343495013, COSV100073311; called by muse, mutect2, varscan2
- PARVA | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1438232541, COSV100616508; called by muse, mutect2, varscan2
- PCDH12 | c.1129A>T p.M377L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV99186508; called by muse, mutect2
- PCDHA5 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV65351209, COSV65352500; called by muse, mutect2, varscan2
- PCDHA8 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.942); catalogued as rs1342346203, COSV100970555; called by muse, mutect2, varscan2
- PCDHAC1 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs386352346, COSV53863427, COSV53873987; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB1 | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 122/180 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100128078; called by muse, mutect2, varscan2
- PCDHB14 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99505676; called by muse, mutect2, varscan2
- PCDHB4 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 87/152 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs782620651, COSV52021200; called by muse, mutect2, varscan2
- PCDHGA4 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as rs559980851, COSV54052258; called by muse, mutect2, varscan2
- PCDHGA5 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770859603, COSV99533770; called by muse, mutect2, varscan2
- PCLO | c.6274A>T p.T2092S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV100429168; called by muse, mutect2, varscan2
- PCOLCE2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV99930481; called by muse, mutect2, varscan2
- PCSK6 | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as rs1181439175, COSV100623683; called by muse, mutect2, varscan2
- PDE1B | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54495764, COSV99672312; called by muse, mutect2, varscan2
- PDE3A | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV62970096; called by muse, mutect2, varscan2
- PDE3A | c.2660T>G p.I887S | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100761957, COSV62975496; called by muse, mutect2, varscan2
- PDZD4 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 56/59 reads (95%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV51253887; called by muse, mutect2, varscan2
- PENK | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100152238, COSV59242846; called by muse, mutect2, varscan2
- PGK2 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV59164995; called by muse, mutect2, varscan2
- PGM2 | c.1719T>G p.C573W | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV101126555; called by muse, mutect2, varscan2
- PHLDB3 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759402249, COSV99415302; called by muse, varscan2
- PI4KA | c.5405C>T p.P1802L | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317931662, COSV99745096; called by muse, mutect2, varscan2
- PIGR | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100732465; called by muse, mutect2, varscan2
- PIGV | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99314815; called by muse, mutect2, varscan2
- PIKFYVE | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV52236288; called by muse, mutect2, varscan2
- PIP5K1C | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs773003605, COSV100095164; called by muse, mutect2, varscan2
- PKHD1L1 | c.2767C>T p.H923Y | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs958715836, COSV65740825; called by muse, mutect2, varscan2
- PLA2G4D | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99299411; called by muse, mutect2, varscan2
- PLCE1 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 55/63 reads (87%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs751519901, COSV99594121; called by muse, mutect2, varscan2
- PLEC | c.11627G>A p.G3876E (on ENST00000322810 / NM_201380.4; = p.G3766E on NM_000445.5) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV100512177; called by muse, mutect2, varscan2
- PLEKHH2 | c.2390G>C p.R797P | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56762203, COSV99174476; called by muse, mutect2, varscan2
- PLEKHS1 | c.763T>C p.F255L (on ENST00000369310 / NM_182601.1; = p.F261L on NM_024889.5) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100613020; called by muse, mutect2, varscan2
- PLXNB1 | c.4264G>T p.D1422Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99602513; called by muse, mutect2, varscan2
- PPP1R13B | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52456200; called by muse, mutect2, varscan2
- PRAMEF14 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100577280; called by muse, mutect2, varscan2
- PRICKLE1 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100453615; called by muse, mutect2, varscan2
- PRKD1 | c.2456T>C p.L819S | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100119576, COSV59570432; called by muse, mutect2, varscan2
- PRPF38B | c.489G>T p.M163I | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV100898230; called by muse, mutect2, varscan2
- PRPF4B | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs143527062; called by muse, mutect2, varscan2
- PSG4 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV54940723; called by muse, mutect2, varscan2
- PTCD1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs757348286, COSV52857425; called by muse, mutect2, varscan2
- PTPN21 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161666; called by muse, mutect2
- RAB11FIP3 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467030433, COSV99240023; called by muse, mutect2, varscan2
- RAB27B | c.239+1G>A p.X80_splice | Splice Site (SNP) | VAF 67/127 reads (53%) | catalogued as rs1386819845, COSV100024010; called by muse, mutect2, varscan2
- RAC2 | c.473C>A p.S158* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99969408; called by muse, mutect2, varscan2
- RAG2 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.1); catalogued as rs757841294, COSV100271155; called by muse, mutect2, varscan2
- RB1CC1 | c.1084A>T p.I362F | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99209219; called by muse, mutect2, varscan2
- RBBP5 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV52702925, COSV99196770; called by muse, mutect2, varscan2
- RBM12 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs886883866, COSV100467234; called by muse, mutect2, varscan2
- RBMY1E | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV100740349; called by muse, mutect2, varscan2
- RCSD1 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV63257921; called by muse, mutect2
- RGS18 | c.55A>T p.K19* | Nonsense Mutation (SNP) | VAF 47/105 reads (45%) | catalogued as COSV100817697; called by muse, mutect2, varscan2
- RNF175 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs377303943; called by muse, mutect2, varscan2
- RNF31 | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100141626; called by muse, mutect2, varscan2
- ROCK2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1325038763, COSV99837145; called by muse, mutect2, varscan2
- RP1 | c.1871A>G p.K624R | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV99606721; called by muse, mutect2, varscan2
- RP1 | c.3265C>T p.H1089Y | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV99606725; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100271534; called by muse, mutect2, varscan2
- RTL1 | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as rs1477497282, COSV101128177, COSV66016432; called by muse, mutect2
- RUFY1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1437536043, COSV100105836; called by muse, mutect2, varscan2
- SALL4 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs373872511, COSV53855018; called by muse, mutect2, varscan2
- SAMHD1 | c.1546C>T p.R516* (on ENST00000262878 / NM_001363729.2; = p.R551* on NM_015474.4) | Nonsense Mutation (SNP) | VAF 29/155 reads (19%) | catalogued as rs149846637; called by muse, mutect2, varscan2
- SASH1 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 55/57 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100821021; called by muse, mutect2, varscan2
- SCAF1 | c.3409C>T p.H1137Y | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100566839; called by muse, mutect2, varscan2
- SCN3A | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs200738468, COSV99326167; called by muse, mutect2, varscan2
- SCNN1A | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV99964590; called by muse, mutect2, varscan2
- SCNN1G | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100264042; called by muse, mutect2, varscan2
- SDR16C5 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as rs1402853244, COSV100373880; called by muse, mutect2, varscan2
- SEL1L3 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV99339817; called by muse, mutect2, varscan2
- SEMA3A | c.2015A>G p.H672R | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99545842; called by muse, mutect2, varscan2
- SETD5 | c.2650G>T p.G884* | Nonsense Mutation (SNP) | VAF 44/99 reads (44%) | catalogued as COSV100200352; called by muse, mutect2, varscan2
- SEZ6L | c.1772A>G p.E591G | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99961642; called by muse, mutect2, varscan2
- SEZ6L | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 78/108 reads (72%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99961643; called by muse, mutect2, varscan2
- SEZ6L2 | c.2703+1G>A p.X901_splice (on ENST00000308713 / NM_001114099.3; = p.X844_splice on NM_012410.4) | Splice Site (SNP) | VAF 17/41 reads (41%) | catalogued as rs770774282, COSV100435247; called by muse, mutect2, varscan2
- SGMS1 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 32/39 reads (82%) | catalogued as COSV100693422, COSV62369102; called by muse, mutect2, varscan2
- SHISA4 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 100/188 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753737766, COSV100748209; called by muse, mutect2, varscan2
- SHROOM3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56042656; called by muse, mutect2, varscan2
- SHROOM3 | c.3748C>T p.R1250C | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs746198913, COSV99933837; called by muse, mutect2, varscan2
- SI | c.5408C>T p.T1803I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV100014561; called by muse, mutect2, varscan2
- SIGLEC6 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV100585262, COSV100585397; called by muse, mutect2
- SIGLEC7 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as rs767198744, COSV58318110; called by muse, mutect2, varscan2
- SIPA1L3 | c.3217C>G p.R1073G | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV99727814; called by muse, mutect2, varscan2
- SLC10A3 | c.211G>C p.G71R | Missense Mutation (SNP) | VAF 73/76 reads (96%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.96); catalogued as COSV99682049; called by muse, mutect2, varscan2
- SLC14A1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354167856, COSV58931596; called by muse, mutect2, varscan2
- SLC15A2 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99815277; called by muse, mutect2, varscan2
- SLC17A8 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.819); catalogued as COSV100035308; called by muse, mutect2, varscan2
- SLC22A16 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100397293; called by muse, mutect2, varscan2
- SLC25A52 | c.263G>A p.R88Q (on ENST00000672005; = p.R78Q on NM_001034172.4) | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs865854821, COSV52501584; called by muse, mutect2, varscan2
- SLC43A1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs778939092, COSV99560831; called by muse, mutect2, varscan2
- SLC5A5 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55833176; called by muse, mutect2, varscan2
- SLC6A1 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV99822559; called by muse, mutect2, varscan2
- SLC9C1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs762076820, COSV59884880; called by muse, mutect2, varscan2
- SLCO6A1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.569); catalogued as COSV101134148; called by muse, mutect2, varscan2
- SLCO6A1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 133/232 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65806914; called by muse, mutect2, varscan2
- SLFN11 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 92/259 reads (36%) | catalogued as COSV100390423; called by muse, mutect2, varscan2
- SLIT1 | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV99820866; called by muse, mutect2, varscan2
- SLITRK3 | c.2144G>C p.G715A | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as COSV99578785; called by muse, mutect2, varscan2
- SLITRK6 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs375069918, COSV68389890; called by muse, mutect2, varscan2
- SLURP1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs760550123, COSV99872844; called by muse, mutect2, varscan2
- SNRNP200 | c.2421G>A p.Q807= | Splice Region (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100107350; called by muse, mutect2, varscan2
- SOST | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100059606; called by muse, mutect2, varscan2
- SPAG17 | c.4544G>A p.G1515E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100308411; called by muse, mutect2, varscan2
- SPATA16 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63531503; called by muse, mutect2, varscan2
- SPATA9 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs1237483898, COSV99174140; called by muse, mutect2, varscan2
- SPHKAP | c.4910G>A p.G1637E (on ENST00000392056 / NM_001142644.2; = p.G1608E on NM_030623.3) | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60875234; called by muse, mutect2, varscan2
- SPHKAP | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100763857; called by muse, mutect2, varscan2
- SPRED3 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | catalogued as COSV100612621; called by muse, mutect2, varscan2
- SPTBN4 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs1158111299, COSV100150356, COSV58955397; called by muse, mutect2, varscan2
- SRCAP | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99349628; called by muse, mutect2, varscan2
- SRGAP3 | c.3064G>A p.D1022N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); catalogued as rs368928818; called by muse, mutect2, varscan2
- STAB1 | c.6530C>T p.S2177L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs763192280, COSV58733618; called by muse, mutect2, varscan2
- STK36 | c.3001C>T p.L1001F | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV55329278; called by muse, mutect2, varscan2
- STRA6 | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100120902; called by muse, mutect2, varscan2
- STX1B | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV99287983; called by muse, mutect2, varscan2
- STXBP5L | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs866206814, COSV56511990, COSV99874789; called by muse, mutect2, varscan2
- TAAR6 | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 102/109 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51582634, COSV51583001; called by muse, mutect2, varscan2
- TARDBP | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99534084; called by muse, mutect2, varscan2
- TARS1 | c.193A>C p.K65Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV99465651; called by muse, mutect2, varscan2
- TBC1D15 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.207); catalogued as COSV100041523; called by muse, mutect2, varscan2
- TBC1D3B | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as rs1416491529; called by mutect2, varscan2
- TBPL2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.076); catalogued as rs147025657; called by muse, mutect2, varscan2
- TCFL5 | c.1409C>T p.T470I | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753338222, COSV99415648; called by muse, mutect2, varscan2
- TEX19 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 142/185 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.51); catalogued as COSV61017088; called by muse, mutect2, varscan2
- TG | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750156538, COSV99599736; called by muse, mutect2, varscan2
- THSD7B | c.3337G>A p.D1113N (on ENST00000272643; = p.D1111N on NM_001316349.2) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV55722167; called by muse, mutect2, varscan2
- TIPARP | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55815671; called by muse, mutect2, varscan2
- TKT | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs1553679757, COSV99964920; called by muse, mutect2, varscan2
- TMPRSS3 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99367801; called by muse, mutect2, varscan2
- TMPRSS9 | c.968C>T p.A323V (on ENST00000648592; = p.A289V on NM_182973.2) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100211171; called by muse, mutect2, varscan2
- TNFRSF8 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as rs746991228, COSV99821225; called by muse, mutect2, varscan2
- TNR | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557913651, COSV99687041, COSV99688435; called by muse, mutect2, varscan2
- TPR | c.3982T>G p.L1328V | Missense Mutation (SNP) | VAF 121/201 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100823747; called by muse, mutect2, varscan2
- TPTE | c.871G>A p.D291N (on ENST00000618007 / NM_199261.4; = p.D273N on NM_199259.4) | Missense Mutation (SNP) | VAF 42/391 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.493); catalogued as rs373367615; called by muse, mutect2, varscan2
- TRAF3 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs775312865, COSV100693505; called by muse, mutect2, varscan2
- TRPM2 | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs750639916, COSV100308388; called by muse, mutect2, varscan2
- TRPM8 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100223774; called by muse, mutect2, varscan2
- TSC2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99552474, COSV99552825; called by muse, mutect2, varscan2
- TSC2 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs773545852, COSV99553199; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TTC21A | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV100087127; called by muse, mutect2, varscan2
- TTN | c.42994G>A p.E14332K (on ENST00000591111; = p.E6908K on NM_003319.4) | Missense Mutation (SNP) | VAF 66/134 reads (49%) | PolyPhen probably damaging (0.915); catalogued as rs375099780; called by muse, mutect2, varscan2
- TTYH1 | c.164T>A p.L55* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV100001856; called by muse, mutect2, varscan2
- UBR2 | c.3886C>T p.P1296S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as rs555549990, COSV100867389; called by muse, mutect2, varscan2
- UNC45A | c.608T>C p.L203S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101265749; called by muse, mutect2, varscan2
- UNC93A | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs376096869, COSV57809581; called by muse, mutect2, varscan2
- UROS | c.391T>C p.S131P | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1350528981, COSV100908866; called by muse, mutect2, varscan2
- USH2A | c.6803A>T p.N2268I | Missense Mutation (SNP) | VAF 223/528 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100231543; called by muse, mutect2, varscan2
- USP2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs199528569, COSV52730532; called by muse, mutect2, varscan2
- USP6 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.867); catalogued as COSV100003487; called by muse, mutect2, varscan2
- UTP20 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1412055124, COSV99881091; called by muse, mutect2, varscan2
- VCL | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs377722209, COSV99281153; called by muse, mutect2, varscan2
- VCPIP1 | c.757T>G p.Y253D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100125441; called by muse, mutect2, varscan2
- VPS13D | c.8051C>T p.S2684F | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV99165803; called by muse, mutect2, varscan2
- VPS18 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99592375; called by muse, mutect2, varscan2
- VPS18 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99592377; called by muse, mutect2, varscan2
- WDFY3 | c.4498G>T p.D1500Y | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429551137, COSV99882643; called by muse, mutect2, varscan2
- WDR25 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100091508; called by muse, mutect2, varscan2
- WDR72 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV64742258, COSV64752288; called by muse, mutect2, varscan2
- WDR82 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 63/128 reads (49%) | catalogued as COSV56602584; called by muse, mutect2, varscan2
- WDR91 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100615619; called by muse, mutect2, varscan2
- WNK1 | c.2984T>G p.V995G | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100266653; called by muse, mutect2, varscan2
- WNK3 | c.3301C>T p.P1101S | Missense Mutation (SNP) | VAF 59/61 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100671018; called by muse, mutect2, varscan2
- WNT9B | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99255046; called by muse, mutect2, varscan2
- XDH | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV101052113; called by muse, mutect2, varscan2
- XPO6 | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100484838; called by muse, mutect2, varscan2
- XYLB | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV99264055; called by muse, mutect2, varscan2
- ZBTB25 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs576357133, COSV67198829; called by muse, mutect2, varscan2
- ZBTB25 | c.735A>T p.E245D | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV101170707; called by muse, mutect2, varscan2
- ZBTB32 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as COSV99385917; called by muse, mutect2, varscan2
- ZNF138 | c.220C>T p.R74C (on ENST00000307355 / NM_001367572.1; = p.R48C on NM_006524.4) | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs370280904; called by muse, mutect2, varscan2
- ZNF154 | c.128T>C p.M43T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101377470; called by muse, mutect2, varscan2
- ZNF160 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV61998868; called by muse, mutect2, varscan2
- ZNF225 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs1254266727, COSV99489364; called by muse, mutect2, varscan2
- ZNF354C | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs749876696, COSV59607174; called by muse, mutect2, varscan2
- ZNF518B | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100456619; called by muse, mutect2, varscan2
- ZNF536 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764634734, COSV62835177; called by muse, mutect2, varscan2
- ZNF551 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV99989841; called by muse, mutect2, varscan2
- ZNF563 | c.53G>A p.W18* | Nonsense Mutation (SNP) | VAF 63/102 reads (62%) | catalogued as COSV99536472; called by muse, mutect2, varscan2
- ZNF600 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100592927; called by muse, mutect2, varscan2
- ZNF69 | c.7T>G p.C3G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); catalogued as COSV100420914; called by muse, mutect2, varscan2
- ZNF776 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs767886595, COSV100414120; called by muse, mutect2, varscan2
- ZNF8 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | catalogued as COSV99544179; called by muse, mutect2, varscan2
- ZNF92 | c.1142C>T p.S381F (on ENST00000328747 / NM_152626.4; = p.S312F on NM_007139.4) | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV100165716; called by muse, mutect2, varscan2
- ZXDC | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100306362; called by muse, mutect2, varscan2
- CDKN2A | c.276_278delinsTA p.T93Sfs*53 | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | called by pindel, varscan2*
- CLYBL | c.899_907del p.A300_K302del | In Frame Del (DEL) | VAF 40/86 reads (47%) | called by mutect2, pindel, varscan2
- DSC3 | c.1521-5_1532del p.X507_splice | Splice Site (DEL) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- GLP2R | c.1089_1113del p.K363Nfs*52 | Frame Shift Del (DEL) | VAF 32/152 reads (21%) | called by mutect2, pindel
- HNRNPUL2 | c.1466_1467del p.V489Afs*31 | Frame Shift Del (DEL) | VAF 55/154 reads (36%) | called by pindel, varscan2
- IGHV3-66 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 93/151 reads (62%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IGSF22 | c.1360G>C p.D454H | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2
- MROH1 | c.2768A>T p.H923L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NR3C1 | c.2222dup p.L741Ffs*3 | Frame Shift Ins (INS) | VAF 40/97 reads (41%) | called by mutect2, pindel, varscan2
- PLEKHH1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); called by muse, mutect2
- SEC24B | c.509_536del p.S170Ffs*82 | Frame Shift Del (DEL) | VAF 60/232 reads (26%) | called by mutect2, pindel
- TMC5 | c.1178del p.Q393Rfs*15 (on ENST00000396229 / NM_001105248.1; = p.Q147Rfs*15 on NM_024780.5) | Frame Shift Del (DEL) | VAF 50/101 reads (50%) | called by mutect2, pindel, varscan2
- USP53 | c.1979del p.G660Efs*11 | Frame Shift Del (DEL) | VAF 54/129 reads (42%) | called by mutect2, pindel, varscan2
- ZNF84 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- A4GNT | c.21C>T p.L7= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99367750; called by muse, mutect2
- ABCA12 | c.3162C>T p.P1054= (on ENST00000272895 / NM_173076.3; = p.P736= on NM_015657.3) | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs1266526621, COSV99789037; called by muse, mutect2, varscan2
- ABHD8 | c.813G>A p.K271= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV56046538, COSV99917171; called by muse, mutect2, varscan2
- ACAD10 | c.1575C>T p.I525= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs1417487696, COSV100563945; called by muse, mutect2, varscan2
- ACAD10 | c.2727C>A p.I909= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV100563951; called by muse, mutect2, varscan2
- ACSBG2 | c.819C>T p.L273= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99397277; called by muse, mutect2, varscan2
- ADAMTS18 | c.2796G>A p.P932= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as rs759564729, COSV99271712; called by muse, mutect2, varscan2
- ADCY10 | c.1185C>T p.I395= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs757261904, COSV63238799; called by muse, mutect2
- AEBP1 | c.987G>A p.E329= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99788559; called by muse, mutect2
- AGO4 | c.1755C>T p.F585= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV100942842; called by muse, mutect2, varscan2
- AHR | c.1458C>T p.F486= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as rs1333676149, COSV99619443; called by muse, mutect2, varscan2
- AKR1D1 | c.669G>A p.G223= | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as COSV99652911; called by muse, mutect2, varscan2
- ALDH2 | c.1305G>A p.G435= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99922797; called by muse, mutect2, varscan2
- ALDOB | c.90C>T p.I30= | Silent (SNP) | VAF 19/21 reads (90%) | catalogued as COSV100878832, COSV66397824; called by muse, mutect2, varscan2
- ALPK2 | c.4380C>T p.T1460= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs375060141, COSV100864491; called by muse, mutect2
- AMY2B | c.522T>C p.D174= | Silent (SNP) | VAF 88/284 reads (31%) | catalogued as rs781722602, COSV100796233; called by muse, mutect2
- ANO4 | c.789C>T p.I263= (on ENST00000392977 / NM_001286615.2; = p.I228= on NM_178826.4) | Silent (SNP) | VAF 65/94 reads (69%) | catalogued as rs371829096; called by muse, mutect2, varscan2
- APLP2 | c.1806C>T p.F602= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs771123042, COSV53845616; called by muse, mutect2, varscan2
- ARHGAP30 | c.2691G>A p.E897= (on ENST00000368013 / NM_001025598.2; = p.E686= on NM_181720.3) | Silent (SNP) | VAF 37/54 reads (69%) | catalogued as COSV100920165; called by muse, mutect2, varscan2
- ARHGAP31 | c.2598G>A p.R866= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV99956773; called by muse, mutect2, varscan2
- ARHGAP33 | c.1014C>T p.F338= | Silent (SNP) | VAF 44/60 reads (73%) | catalogued as COSV99137745; called by muse, mutect2, varscan2
- ARHGEF10L | c.1167C>T p.S389= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as rs762962162, COSV99392305; called by muse, mutect2, varscan2
- ATP13A3 | c.2643T>C p.C881= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99756559; called by muse, mutect2, varscan2
- B3GAT1 | c.30C>T p.I10= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1165399108, COSV56994633; called by muse, mutect2, varscan2
- BPIFB4 | c.900G>A p.G300= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100971465; called by muse, mutect2, varscan2
- BTNL8 | c.579C>T p.I193= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV99180437; called by muse, mutect2, varscan2
- CACNA1E | c.2983C>T p.L995= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs1172836483, COSV100701553; called by muse, mutect2, varscan2
- CASP10 | c.1227C>T p.S409= (on ENST00000272879 / NM_032974.5; = p.S366= on NM_001230.5) | Silent (SNP) | VAF 60/90 reads (67%) | catalogued as rs371401141; ClinVar: likely benign; called by muse, mutect2, varscan2
- CBLN2 | c.507G>A p.V169= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99504228; called by muse, mutect2, varscan2
- CDCA2 | c.2337C>T p.C779= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100398786; called by muse, mutect2, varscan2
- CDH7 | c.516G>A p.V172= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs1414817630, COSV100541755; called by muse, mutect2, varscan2
- CDSN | c.990G>A p.V330= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as COSV99456730; called by muse, mutect2, varscan2
- CENPF | c.4797G>A p.R1599= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100871590; called by muse, mutect2, varscan2
- CEP290 | c.930A>T p.V310= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs1446326901, COSV100468132; called by muse, mutect2, varscan2
- CES5A | c.345C>T p.F115= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs766399736, COSV99307254; called by muse, mutect2, varscan2
- CIITA | c.2226G>A p.R742= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV60861506; called by muse, mutect2, varscan2
- CLSTN3 | c.1890G>A p.E630= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99866694, COSV99867279; called by muse, mutect2, varscan2
- CMYA5 | c.11661G>A p.Q3887= | Silent (SNP) | VAF 101/181 reads (56%) | catalogued as COSV101405651, COSV69745688; called by muse, mutect2, varscan2
- COL2A1 | c.468G>A p.G156= | Silent (SNP) | VAF 56/87 reads (64%) | catalogued as rs776531707, COSV100475882; called by muse, mutect2, varscan2
- COL3A1 | c.1857C>T p.P619= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs769323072, COSV100482713; called by muse, mutect2, varscan2
- COL5A1 | c.4887G>A p.L1629= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV100879685, COSV100880711; called by muse, mutect2, varscan2
- COLEC12 | c.777G>A p.K259= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV101232007; called by muse, mutect2
- CP | c.759C>T p.F253= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs978944744, COSV99223871; called by muse, mutect2, varscan2
- CPAMD8 | c.4386C>T p.S1462= (on ENST00000651564; = p.S1415= on NM_015692.5) | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs758288898, COSV101488442; called by muse, varscan2
- CREB3L1 | c.1140C>T p.A380= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs766160168, COSV99914892; called by muse, mutect2, varscan2
- CUX2 | c.3891G>A p.R1297= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV99919055; called by muse, mutect2, varscan2
- CYBB | c.1330C>T p.L444= | Silent (SNP) | VAF 61/63 reads (97%) | catalogued as rs1556471633, COSV101059704; called by muse, mutect2, varscan2
- CYP3A4 | c.657C>T p.F219= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV100315527, COSV60501206; called by muse, mutect2, varscan2
- DCAF4L2 | c.966G>A p.V322= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV100150620, COSV60479982; called by muse, mutect2, varscan2
- DLGAP1 | c.1539G>A p.S513= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100228861; called by muse, mutect2
- DNAH5 | c.11679C>T p.F3893= | Silent (SNP) | VAF 48/84 reads (57%) | catalogued as COSV54204715; called by muse, mutect2, varscan2
- DNAH5 | c.9552C>T p.G3184= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54203231; called by muse, mutect2, varscan2
- DNAH8 | c.8352C>T p.I2784= | Silent (SNP) | VAF 164/333 reads (49%) | catalogued as COSV59443162, COSV59443625; called by muse, mutect2, varscan2
- DROSHA | c.1437T>C p.S479= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100757538; called by muse, mutect2, varscan2
- DSE | c.1242C>T p.F414= | Silent (SNP) | VAF 72/78 reads (92%) | catalogued as COSV59063190; called by muse, mutect2, varscan2
- DSG3 | c.249C>T p.I83= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs1357861394, COSV99933928; called by muse, mutect2, varscan2
- EBF3 | c.573C>T p.F191= | Silent (SNP) | VAF 26/27 reads (96%) | catalogued as rs778039418, COSV62481884; called by muse, mutect2, varscan2
- EBI3 | c.117G>A p.R39= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs748118407, COSV99696030; called by muse, mutect2
- ELAVL4 | c.897C>T p.I299= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100836631; called by muse, mutect2, varscan2
- ELP2 | c.669C>T p.F223= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as rs1209385512, COSV100626760; called by muse, mutect2, varscan2
- ENPEP | c.48G>A p.T16= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs1225718514, COSV54454125; called by muse, mutect2, varscan2
- ERC2 | c.324A>G p.G108= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99882470; called by muse, mutect2, varscan2
- F2RL1 | c.720C>T p.F240= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV99688696; called by muse, mutect2, varscan2
- FAM193A | c.1200A>G p.T400= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV100218784; called by muse, mutect2, varscan2
- FAM83H | c.351C>T p.F117= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV66353841; called by muse, mutect2, varscan2
- FAT4 | c.13305C>T p.H4435= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs1357034003, COSV100627760; called by muse, mutect2, varscan2
- FBN3 | c.7812C>T p.A2604= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99560327; called by muse, mutect2, varscan2
- FLII | c.3135G>A p.R1045= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs1401896254, COSV100375167; called by muse, mutect2, varscan2
- FRG2C | c.147C>T p.S49= | Silent (SNP) | VAF 22/258 reads (9%) | called by muse, mutect2
- FRY | c.3960C>T p.A1320= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV66565765; called by muse, mutect2
- FRYL | c.219C>T p.S73= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV99976327; called by muse, mutect2, varscan2
- GHITM | c.378C>T p.S126= | Silent (SNP) | VAF 44/47 reads (94%) | catalogued as COSV100930051; called by muse, mutect2, varscan2
- GLDC | c.1557C>T p.F519= | Silent (SNP) | VAF 28/31 reads (90%) | catalogued as COSV58683838; called by muse, mutect2, varscan2
- GLIS1 | c.675G>A p.K225= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs990922501, COSV100389649; called by muse, mutect2, varscan2
- GOT1L1 | c.1200C>T p.L400= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as COSV56874463; called by muse, mutect2, varscan2
- GPER1 | c.810C>T p.V270= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV99866823; called by muse, mutect2, varscan2
- GPR158 | c.2484G>A p.T828= | Silent (SNP) | VAF 66/73 reads (90%) | catalogued as rs1218891774, COSV100893006; called by muse, mutect2, varscan2
- GPRIN1 | c.1569C>T p.S523= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99991229; called by muse, mutect2, varscan2
- H1-4 | c.327G>A p.K109= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs1387610611, COSV56800081, COSV99175236; called by muse, mutect2, varscan2
- HBE1 | c.336G>A p.V112= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV53079544; called by muse, mutect2, varscan2
- HDAC9 | c.1707T>G p.A569= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV101286584; called by muse, mutect2, varscan2
- HOXA2 | c.660C>T p.S220= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as COSV56066291, COSV56067168; called by muse, mutect2, varscan2
- HS3ST2 | c.489C>T p.S163= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV99757808; called by muse, mutect2, varscan2
- HS3ST2 | c.490C>T p.L164= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV99757811; called by muse, mutect2, varscan2
- IGHD | c.867C>T p.A289= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101162816; called by muse, mutect2, varscan2
- IGSF21 | c.1377C>T p.A459= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99244167; called by muse, mutect2, varscan2
- IL1R1 | c.219G>A p.R73= | Silent (SNP) | VAF 71/100 reads (71%) | catalogued as COSV99292468; called by muse, mutect2, varscan2
- IPO11 | c.2361G>A p.V787= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as rs1482333412, COSV100320402; called by muse, mutect2, varscan2
- KDM4B | c.1524C>T p.V508= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs140977454; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT34 | c.54G>A p.R18= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1435696816, COSV101222581; called by muse, mutect2, varscan2
- KRTAP8-1 | c.156C>T p.F52= | Silent (SNP) | VAF 65/113 reads (58%) | catalogued as rs201803377, COSV61597805; called by muse, mutect2, varscan2
- KYNU | c.177A>G p.L59= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV99932947; called by muse, mutect2
- LDLRAP1 | c.124C>T p.L42= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100974702; called by muse, mutect2, varscan2
- LGR6 | c.1779C>T p.P593= (on ENST00000367278 / NM_001017403.1; = p.P541= on NM_021636.3) | Silent (SNP) | VAF 65/109 reads (60%) | catalogued as rs938810105, COSV99706384; called by muse, mutect2, varscan2
- LILRB1 | c.297A>G p.E99= (on ENST00000427581; = p.E63= on NM_006669.6) | Silent (SNP) | VAF 33/164 reads (20%) | catalogued as COSV100207065; called by muse, mutect2, varscan2
- LIPK | c.720C>T p.F240= | Silent (SNP) | VAF 85/91 reads (93%) | catalogued as COSV101344960; called by muse, mutect2, varscan2
- LONRF1 | c.1887G>T p.V629= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as rs766262190, COSV101238189; called by muse, mutect2, varscan2
- LPAR3 | c.531T>G p.S177= | Silent (SNP) | VAF 63/99 reads (64%) | catalogued as COSV101004704; called by muse, mutect2, varscan2
- LRIG1 | c.2181C>T p.F727= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as COSV99833423; called by muse, mutect2, varscan2
- LRIT2 | c.939C>T p.A313= | Silent (SNP) | VAF 35/39 reads (90%) | catalogued as rs767067229, COSV100258598; called by muse, mutect2, varscan2
- LRP1 | c.5076C>T p.S1692= | Silent (SNP) | VAF 51/82 reads (62%) | catalogued as COSV99675055; called by muse, mutect2, varscan2
- LRRC37A2 | c.3828C>T p.T1276= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV100238672; called by muse, mutect2
- MAGEA12 | c.612C>T p.I204= | Silent (SNP) | VAF 132/136 reads (97%) | catalogued as rs1556833534, COSV63295561; called by muse, mutect2, varscan2
- MAMSTR | c.810G>A p.P270= (on ENST00000318083 / NM_001130915.2; = p.P167= on NM_182574.2) | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100540357; called by muse, mutect2, varscan2
- MAP1S | c.420C>T p.F140= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs780401305, COSV100140920; called by muse, mutect2, varscan2
- MAP2K1 | c.378C>T p.I126= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs369401783; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1926C>T p.F642= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1281565147, COSV50498885; called by muse, mutect2, varscan2
- MARCHF7 | c.1446C>T p.S482= | Silent (SNP) | VAF 91/273 reads (33%) | catalogued as rs1397526625, COSV99373608; called by muse, mutect2, varscan2
- MDM1 | c.87C>T p.S29= | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as rs1324285271, COSV57445534; called by muse, mutect2, varscan2
- MED24 | c.384C>T p.L128= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as COSV100673047; called by muse, mutect2, varscan2
- MNDA | c.81C>T p.S27= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs562131738, COSV100933279, COSV63741120; called by muse, mutect2, varscan2
- MS4A7 | c.711G>A p.R237= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV55729032; called by muse, mutect2, varscan2
- MUC16 | c.22656G>A p.E7552= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as COSV101198871; called by muse, mutect2, varscan2
- MUC16 | c.15804G>A p.T5268= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV101198873; called by muse, mutect2, varscan2
- MYCBP2 | c.606C>T p.G202= (on ENST00000357337; = p.G240= on NM_015057.5) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1475823350, COSV100629587; called by muse, mutect2, varscan2
- MYH14 | c.4971G>A p.K1657= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1287461412, COSV99222154; called by muse, mutect2, varscan2
- MYH2 | c.2136G>A p.R712= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs768172624, COSV99819613; called by muse, mutect2, varscan2
- MYH4 | c.1476C>T p.F492= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as COSV55122114, COSV55122316, COSV55125975; called by muse, mutect2, varscan2
- MYO6 | c.1419C>A p.I473= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs1362005158, COSV100889331; called by muse, mutect2, varscan2
- NDUFB3 | c.186C>T p.S62= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99428281, COSV99428339; called by muse, mutect2, varscan2
- NLGN4X | c.2106G>A p.K702= | Silent (SNP) | VAF 48/49 reads (98%) | catalogued as rs755522754, COSV99320610; called by muse, mutect2, varscan2
- NLRP13 | c.1713A>G p.Q571= | Silent (SNP) | VAF 70/109 reads (64%) | catalogued as rs1301442339, COSV100738098; called by muse, mutect2, varscan2
- NLRP5 | c.2139G>A p.P713= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as rs150731041; called by muse, mutect2, varscan2
- NME7 | c.720C>T p.T240= | Silent (SNP) | VAF 200/361 reads (55%) | catalogued as COSV100890948; called by muse, mutect2, varscan2
- NOTCH2 | c.1335G>A p.L445= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV99863236; called by muse, mutect2, varscan2
- NPHP3 | c.2472G>T p.L824= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs750242085, COSV100446689; called by muse, mutect2, varscan2
- NWD1 | c.3526C>T p.L1176= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as COSV100342031; called by muse, mutect2, varscan2
- OR10G4 | c.180C>T p.F60= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100304752; called by muse, mutect2, varscan2
- OR10K1 | c.153G>A p.L51= | Silent (SNP) | VAF 90/175 reads (51%) | catalogued as COSV56874975; called by muse, mutect2, varscan2
- OR10Q1 | c.648C>T p.F216= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100372192, COSV100372319; called by muse, mutect2, varscan2
- OR5D13 | c.105C>T p.F35= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as rs775172669, COSV62332845; called by muse, mutect2, varscan2
- OR6X1 | c.612G>A p.V204= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs868354748, COSV100020473; called by muse, mutect2, varscan2
- OR8B2 | c.771C>T p.F257= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs774728733, COSV100899356, COSV66664824; called by muse, mutect2, varscan2
- OR8D2 | c.846C>T p.I282= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV62488561; called by muse, mutect2, varscan2
- PCDHA3 | c.2013G>A p.E671= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as COSV100793248; called by muse, mutect2, varscan2
- PCDHAC1 | c.2397G>A p.R799= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as COSV99165336; called by muse, mutect2, varscan2
- PCDHGA1 | c.1926C>T p.L642= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV65294783; called by muse, mutect2, varscan2
- PCDHGB6 | c.717C>T p.P239= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV54029567; called by muse, mutect2, varscan2
- PCNX1 | c.3372C>T p.F1124= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99454809; called by muse, mutect2, varscan2
- PCSK6 | c.2658C>T p.Y886= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100623684; called by muse, mutect2, varscan2
- PFKL | c.450C>T p.A150= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs868021005, COSV100827046; called by muse, mutect2, varscan2
- PLD1 | c.3069C>T p.P1023= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs932577500, COSV100643800; called by muse, mutect2, varscan2
- PLVAP | c.51C>T p.S17= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs1007232595, COSV99391549; called by muse, mutect2, varscan2
- PPP1R26 | c.615C>T p.S205= | Silent (SNP) | VAF 30/31 reads (97%) | catalogued as rs1460850987, COSV100778022; called by muse, mutect2, varscan2
- PREX2 | c.3864G>A p.Q1288= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV99905869; called by muse, mutect2, varscan2
- PTPRT | c.2622G>A p.L874= | Silent (SNP) | VAF 64/88 reads (73%) | catalogued as COSV100626063; called by muse, mutect2, varscan2
- PXDNL | c.2586C>T p.F862= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs754744909, COSV62493734; called by muse, mutect2, varscan2
- RAE1 | c.369C>T p.I123= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as rs772373086, COSV100982384; called by muse, mutect2, varscan2
- RAPGEF3 | c.2628C>T p.D876= (on ENST00000389212; = p.D834= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV99406007; called by muse, mutect2, varscan2
- RASGRF2 | c.1425G>A p.G475= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as rs775545658, COSV99428769; called by muse, mutect2, varscan2
- RBMY1E | c.1197C>T p.T399= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as rs763239723, COSV100740348; called by muse, mutect2, varscan2
- RFX6 | c.828G>A p.L276= | Silent (SNP) | VAF 40/43 reads (93%) | catalogued as COSV60587791; called by muse, mutect2, varscan2
- RGS18 | c.366C>T p.F122= | Silent (SNP) | VAF 78/144 reads (54%) | catalogued as COSV66509255; called by muse, mutect2, varscan2
- RHBDD2 | c.219C>T p.P73= | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as COSV99138215; called by muse, mutect2, varscan2
- RUNX1T1 | c.963G>A p.R321= (on ENST00000265814 / NM_001198628.1; = p.R294= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/202 reads (50%) | catalogued as rs371664119; called by muse, mutect2, varscan2
- SCN5A | c.729G>A p.L243= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100347111; called by muse, mutect2, varscan2
- SCN7A | c.2934C>A p.I978= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1263059484, COSV101313158, COSV69273637; called by muse, mutect2
- SDR16C5 | c.504C>T p.D168= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as rs1179031317, COSV58129159; called by muse, mutect2, varscan2
- SGK3 | c.750C>T p.F250= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV100616615; called by muse, mutect2, varscan2
- SHANK1 | c.3426C>T p.P1142= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs769186319, COSV99520579; called by muse, mutect2, varscan2
- SLC24A4 | c.1731C>T p.H577= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100104649; called by muse, mutect2, varscan2
- SLC44A5 | c.1488C>T p.I496= | Silent (SNP) | VAF 82/122 reads (67%) | catalogued as COSV63758769, COSV63764629; called by muse, mutect2, varscan2
- SLC45A4 | c.978C>T p.F326= (on ENST00000517878 / NM_001286646.2; = p.F275= on NM_001080431.2) | Silent (SNP) | VAF 61/122 reads (50%) | catalogued as COSV99196694; called by muse, mutect2, varscan2
- SMPD1 | c.1560C>T p.I520= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV100192510; called by muse, mutect2, varscan2
- SNRNP200 | c.1758C>T p.I586= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs759887489, COSV60490103; called by muse, mutect2, varscan2
- SRGAP2 | c.2934C>T p.P978= (on ENST00000624873 / NM_001170637.4; = p.P979= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV55333042; called by muse, mutect2, varscan2
- STYK1 | c.516G>A p.G172= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99311711; called by muse, mutect2, varscan2
- SULT2A1 | c.846C>T p.F282= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV99705349; called by muse, mutect2, varscan2
- SYNE1 | c.21981C>G p.L7327= (on ENST00000367255 / NM_182961.4; = p.L7256= on NM_033071.3) | Silent (SNP) | VAF 69/76 reads (91%) | catalogued as rs148868250, COSV99557330, COSV99557478; called by muse, mutect2, varscan2
- TAFA5 | c.366C>T p.P122= (on ENST00000402357 / NM_001082967.3; = p.P115= on NM_015381.7) | Silent (SNP) | VAF 48/85 reads (56%) | catalogued as rs772628499, COSV60977812; called by muse, mutect2, varscan2
- THEMIS | c.1248C>T p.I416= | Silent (SNP) | VAF 49/54 reads (91%) | catalogued as COSV64071345; called by muse, mutect2, varscan2
- TMC3 | c.432C>T p.F144= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs1341533235, COSV100845865; called by muse, mutect2, varscan2
- TMEM104 | c.1026C>T p.F342= | Silent (SNP) | VAF 200/248 reads (81%) | catalogued as rs562626910, COSV59108758, COSV59109202; called by muse, mutect2, varscan2
- TMEM25 | c.597C>T p.L199= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1555060458, COSV100244728; called by muse, mutect2, varscan2
- TMEM39A | c.1020C>T p.S340= | Silent (SNP) | VAF 73/139 reads (53%) | catalogued as rs1375661644, COSV59900420; called by muse, mutect2, varscan2
- TOB1 | c.648C>T p.L216= | Silent (SNP) | VAF 103/125 reads (82%) | catalogued as COSV52150977, COSV99278772; called by muse, mutect2, varscan2
- TP53AIP1 | c.282C>T p.F94= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs267602776, COSV101513090; called by muse, varscan2
- TP63 | c.558C>T p.T186= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs200355416, COSV99286077; called by muse, mutect2, varscan2
- TRBJ2-1 | c.45C>T p.T15= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as rs782197888; called by muse, mutect2, varscan2
- TRIO | c.909C>T p.D303= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV100710071; called by muse, mutect2, varscan2
- TRPC7 | c.282G>A p.T94= | Silent (SNP) | VAF 56/91 reads (62%) | catalogued as rs750933488, COSV61462847; called by muse, mutect2, varscan2
- TRPV5 | c.1578C>T p.Y526= | Silent (SNP) | VAF 47/82 reads (57%) | catalogued as rs747402135, COSV99520245; called by muse, mutect2, varscan2
- TSHZ2 | c.1866G>A p.E622= | Silent (SNP) | VAF 66/85 reads (78%) | catalogued as COSV100295651; called by muse, mutect2, varscan2
- TXLNB | c.96G>A p.K32= | Silent (SNP) | VAF 74/79 reads (94%) | catalogued as rs776682700, COSV100624881; called by muse, mutect2, varscan2
- UBQLN4 | c.1704C>T p.S568= | Silent (SNP) | VAF 83/130 reads (64%) | catalogued as COSV100849294; called by muse, mutect2, varscan2
- USP47 | c.3768A>C p.R1256= (on ENST00000399455 / NM_001372095.1; = p.R1168= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV100359320; called by muse, mutect2, varscan2
- VRTN | c.1404G>A p.G468= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99832163; called by muse, mutect2, varscan2
- WDFY3 | c.4497G>A p.Q1499= | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as COSV99882645; called by muse, mutect2, varscan2
- WDR33 | c.3759T>C p.P1253= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as rs1260214155, COSV100205247; called by muse, mutect2, varscan2
- ZNF23 | c.1764C>T p.F588= | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as COSV100612089; called by muse, mutect2, varscan2
- ZNF263 | c.666G>A p.V222= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs751240448, COSV99526779; called by muse, mutect2, varscan2
- ZNF335 | c.1944C>T p.P648= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100532787; called by muse, mutect2, varscan2
- ZNF638 | c.2211T>A p.L737= | Silent (SNP) | VAF 62/104 reads (60%) | catalogued as COSV100038265; called by muse, mutect2, varscan2
- ZYX | c.1449C>T p.I483= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs574219835, COSV99313678; called by muse, mutect2, varscan2
- C3orf84 | c.141+153C>T | Intron (SNP) | VAF 33/78 reads (42%) | catalogued as COSV101410313; called by muse, mutect2, varscan2
- DLG2 | c.259-3445G>T | Intron (SNP) | VAF 19/59 reads (32%) | catalogued as rs767903197; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457470 C>T | 5'Flank (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457896 G>A | 5'Flank (SNP) | VAF 17/70 reads (24%) | catalogued as rs749775437; called by muse, mutect2, varscan2
- HMGB1P1 | n.173G>A | RNA (SNP) | VAF 95/157 reads (61%) | catalogued as rs1320472377; called by muse, mutect2, varscan2
- INSIG1 | c.804+986C>T | Intron (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100452908; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86024C>T | Intron (SNP) | VAF 90/196 reads (46%) | catalogued as COSV72283448; called by muse, mutect2, varscan2
- MIR134 | n.68A>G | RNA (SNP) | VAF 8/23 reads (35%) | catalogued as rs752786233; called by muse, mutect2, varscan2
- MRPL17 | c.-1C>T | 5'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99996814; called by muse, mutect2, varscan2
- OR2W5 | n.1015G>T | RNA (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.461G>A | RNA (SNP) | VAF 23/54 reads (43%) | catalogued as rs539390464; called by muse, mutect2, varscan2
- RTN1 | c.1766-23001C>G | Intron (SNP) | VAF 87/140 reads (62%) | catalogued as COSV99955004; called by muse, mutect2, varscan2
- SPSB2 | c.-2C>T | 5'UTR (SNP) | VAF 15/23 reads (65%) | catalogued as COSV99222830, COSV99222857; called by muse, mutect2, varscan2
- TTN | c.10360+3524G>A | Intron (SNP) | VAF 67/115 reads (58%) | catalogued as rs867888869, COSV59910271, COSV60183960; called by muse, mutect2, varscan2
- XIST | n.10206G>A | RNA (SNP) | VAF 18/19 reads (95%) | called by muse, mutect2, varscan2
